CCDI case PBCBLV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/21e2e6cd-8896-41c7-820d-d8b4cd4ef34b

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,358 days).

Biospecimens (3 samples)
- Sample 0DN9EJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN9ER: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DN9EZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
